TCGA case TCGA-29-1763 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/242da7d0-8c6a-4395-9a0d-aa36e7c25ce6

Demographics
Sex at birth: female; Race: black or african american; Age at index: 43 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 43.9 years (16,021 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 2,032 days (5.6 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 100 days; Number of cycles: 5; Treatment dose: 3,175 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 100 days; Number of cycles: 5; Treatment dose: 1,645 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 450 days (1.2 years); Days to treatment end: 579 days (1.6 years); Number of cycles: 6; Treatment dose: 675 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,283 days (3.5 years); Days to treatment end: 1,325 days (3.6 years); Number of cycles: 4; Treatment dose: 2,000 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,346 days (3.7 years); Days to treatment end: 1,367 days (3.7 years); Number of cycles: 2; Treatment dose: 435 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,346 days (3.7 years); Days to treatment end: 1,376 days (3.8 years); Number of cycles: 3; Treatment dose: 350 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,727 days (4.7 years); Days to treatment end: 1,839 days (5.0 years); Number of cycles: 6; Treatment dose: 350 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 1,948 days (5.3 years); Days to treatment end: 1,979 days (5.4 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 2,049 days (5.6 years); Days to treatment end: 2,161 days (5.9 years); Treatment dose: 1,000 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,049 days (5.6 years); Days to treatment end: 2,126 days (5.8 years); Number of cycles: 4; Treatment dose: 80 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,189 days (6.0 years); Days to treatment end: 2,252 days (6.2 years); Number of cycles: 3; Treatment dose: 6 AUC; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 45.0 years (16,449 days); Days to diagnosis: 428 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,868 days (5.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (4 entries)
- Day 428 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 428 days (1.2 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 2,032 days (5.6 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Other.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Biopsy with Histologic Confirmation; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-29-1763-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-29-1763-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-29-1763-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Gemcitabine HCL.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,032 days; disease-specific survival: no event (censored), 2,032 days; disease-free interval: event (new tumor event after initially disease-free), 428 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 428 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1763-01A-02D-0559-01): tumor purity 0.74, ploidy 3.02, whole-genome doublings 1.
